Somatic mutation profile of tumor specimen TCGA-HT-8110-01A (aliquot TCGA-HT-8110-01A-11D-2395-08) from TCGA case TCGA-HT-8110, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.0 years (21,183 days).
Specimen TCGA-HT-8110-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bd1c971d-88ee-464b-88b9-3e82f30ed901.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8110-10A (Blood Derived Normal), aliquot TCGA-HT-8110-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46390eb7-4e8e-45c0-bae9-902de2d3b89f

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 21, Silent 12, Frame Shift Del 2, Splice Site 2, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 691/736 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519828, COSV51766433; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACADS | c.796-1G>A p.X266_splice | Splice Site (SNP) | VAF 10/47 reads (21%) | catalogued as COSV54369532; called by muse, mutect2, varscan2
- ADCY7 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as rs199712113; called by muse, mutect2, varscan2
- BOD1L1 | c.7696A>G p.S2566G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs773567290, COSV50025387; called by muse, mutect2, varscan2
- CACNG3 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248441351, COSV50064358; called by muse, mutect2, varscan2
- CBFA2T3 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51929612; called by muse, mutect2, varscan2
- CDCA7L | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs899524730, COSV62260023; called by muse, mutect2, varscan2
- CREBBP | c.4990C>T p.R1664C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52114474; called by muse, mutect2, varscan2
- F7 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs779834113, CM004521, COSV60646815; called by muse, mutect2, varscan2
- FAIM | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | catalogued as COSV58158696; called by muse, mutect2, varscan2
- H3-3A | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV100831247, COSV64733188; called by muse, mutect2, varscan2
- HEATR1 | c.2576A>T p.D859V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as COSV63982014; called by muse, mutect2
- HHIP | c.1622G>A p.G541E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.729); catalogued as rs199900341, COSV56841452, COSV56844761; called by muse, mutect2, varscan2
- IMPDH2 | c.418T>A p.C140S | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58708335; called by muse, mutect2, varscan2
- KCNK10 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs373732858; called by muse, mutect2, varscan2
- NLRP1 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs201070268; called by muse, mutect2, varscan2
- NTN4 | c.203C>T p.T68M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.436); catalogued as rs749560184, COSV59220619; called by muse, mutect2, varscan2
- OBSCN | c.5263G>A p.D1755N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as rs369449033; called by muse, mutect2, varscan2
- OR2T27 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as rs1342572684, COSV61283116; called by muse, varscan2
- PCDH11X | c.2473G>A p.V825I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377250651, COSV53454579; called by muse, mutect2, varscan2
- PRDM9 | c.877T>A p.W293R | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV57009545; called by muse, mutect2, varscan2
- PTEN | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV64290003, COSV64299893; called by muse, mutect2, varscan2
- RABEPK | c.1086del p.Y363Mfs*6 | Frame Shift Del (DEL) | VAF 27/119 reads (23%) | catalogued as COSV99413208; called by mutect2, pindel, varscan2
- SHD | c.716+1G>A p.X239_splice | Splice Site (SNP) | VAF 26/69 reads (38%) | catalogued as COSV73378753; called by muse, mutect2, varscan2
- SPATA2 | c.926C>T p.P309L | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.09); catalogued as rs183875038, COSV56867399; called by muse, mutect2, varscan2
- TTN | c.62977G>C p.G20993R (on ENST00000591111; = p.G13569R on NM_003319.4) | Missense Mutation (SNP) | VAF 12/46 reads (26%) | PolyPhen possibly damaging (0.748); catalogued as COSV60176974; called by muse, mutect2, varscan2
- PLCE1 | c.5158del p.S1720Lfs*41 | Frame Shift Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel, varscan2
- ACKR2 | c.1146A>G p.K382= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV56178718; called by muse, mutect2
- B4GALT1 | c.492C>T p.G164= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs763365049, COSV65708466; called by muse, mutect2, varscan2
- C5 | c.12G>A p.L4= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV56329588; called by muse, mutect2, varscan2
- GSDMB | c.123G>A p.G41= | Silent (SNP) | VAF 31/116 reads (27%) | catalogued as COSV58346036; called by muse, mutect2, varscan2
- IFITM1 | c.243C>T p.T81= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs1054925265, COSV60249593; called by muse, mutect2, varscan2
- IGLV11-55 | c.294G>A p.A98= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs377766348; called by muse, mutect2, varscan2
- IQGAP3 | c.4320C>G p.V1440= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV63252934; called by muse, mutect2, varscan2
- LEP | c.21C>T p.C7= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs201523305; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- PRICKLE4 | c.411C>T p.C137= (on ENST00000359201; = p.C177= on NM_013397.6) | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as rs769228438, COSV59256101; called by muse, mutect2, varscan2
- RXRG | c.390C>T p.S130= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs1452854810, COSV63232510; called by muse, mutect2, varscan2
- SCAPER | c.1044G>A p.V348= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV57745206; called by muse, mutect2
- SRBD1 | c.2607G>A p.E869= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV55401410; called by muse, mutect2, varscan2
